Somatic mutation profile of tumor specimen 0DW6BR from CCDI case PBCNLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.1 years (4,065 days).
Specimen 0DW6BR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9171b1ce-0a38-4fa7-beba-b450c2ae5195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6B0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9727a082-72b7-4f3f-8ee2-b1e085d2303e

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 93/1210 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775076049; called by muse, mutect2
- SYNE2 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 91/1070 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs774232167; ClinVar: likely benign; called by muse, mutect2
- EIF4G1 | c.2675G>A p.R892Q (on ENST00000346169 / NM_198241.3; = p.R697Q on NM_004953.5) | Missense Mutation (SNP) | VAF 43/1224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- USH2A | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 90/1835 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2
- LY6G5C | c.346-1026C>G | Intron (SNP) | VAF 290/680 reads (43%) | catalogued as COSV65498042; called by muse, mutect2, varscan2
